BEATAML1.0 case 2595 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Leukemias, NOS; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/1327d1d5-7288-4e86-874b-6ffa191960a1

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Mixed phenotype acute leukemia, T/myeloid, NOS: ICD-O-3 morphology code: 9809/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.4 years (134 days); Progression or recurrence: no.

Biospecimens (2 samples)
- Sample BA3300D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA3300R: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
